Somatic mutation profile of tumor specimen 0DO7MC from CCDI case PBBZVE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 17.7 years (6,457 days).
Specimen 0DO7MC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cd2897d-8816-4d97-be32-3a3426ddd187.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DO7LW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7575ffc-3799-4879-a0f2-e5f3317f93eb

The open-access MAF lists 46 somatic variants for this specimen: 23 protein-altering or splice-affecting, 15 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 15, Intron 4, 5'UTR 3, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GP6 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 54/594 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as rs575231122, COSV100117568; called by muse, mutect2
- GPR101 | c.1282G>T p.E428* | Nonsense Mutation (SNP) | VAF 114/352 reads (32%) | catalogued as COSV53237353; called by muse, mutect2, varscan2
- HAT1 | c.1216G>A p.V406M | Missense Mutation (SNP) | VAF 120/588 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.373); catalogued as rs757792643; called by muse, varscan2
- NKX1-1 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 27/450 reads (6%) | SIFT deleterious, low confidence (0); catalogued as rs1253722009; called by muse, mutect2
- PDZD4 | c.2254C>T p.R752C | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs782511562; called by muse, mutect2, varscan2
- PKD1 | c.5911G>A p.V1971M | Missense Mutation (SNP) | VAF 65/355 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs140434415; called by muse, mutect2, varscan2
- RP1 | c.2936C>T p.A979V | Missense Mutation (SNP) | VAF 68/403 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs1184691680; called by muse, mutect2, varscan2
- SLC23A2 | c.1370G>A p.R457H | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1313457895, COSV57772281; called by muse, mutect2
- SRCAP | c.6451C>T p.R2151C | Missense Mutation (SNP) | VAF 66/744 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99349117; called by muse, mutect2
- TNKS2 | c.3034C>T p.R1012W | Missense Mutation (SNP) | VAF 84/901 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751042631; called by muse, mutect2
- ANKRD44 | c.1337C>A p.A446D | Missense Mutation (SNP) | VAF 56/932 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ATAD1 | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 48/1052 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2
- ATG9A | c.265T>G p.Y89D | Missense Mutation (SNP) | VAF 94/1100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 34/1030 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CA4 | c.773A>G p.Y258C | Missense Mutation (SNP) | VAF 85/613 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDYL2 | c.735C>A p.S245R | Missense Mutation (SNP) | VAF 37/623 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- IQGAP2 | c.4497A>C p.Q1499H | Missense Mutation (SNP) | VAF 29/427 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- MAML2 | c.524C>A p.S175Y | Missense Mutation (SNP) | VAF 72/970 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PITHD1 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 56/1001 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2
- PKNOX2 | c.869A>G p.N290S | Missense Mutation (SNP) | VAF 82/443 reads (19%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SALL3 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF692 | c.1532A>C p.Q511P | Missense Mutation (SNP) | VAF 36/731 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- ZNF880 | c.564G>T p.E188D | Missense Mutation (SNP) | VAF 54/715 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2
- CCPG1 | c.1395T>C p.D465= | Silent (SNP) | VAF 76/747 reads (10%) | catalogued as rs376261837; called by muse, mutect2
- CDH7 | c.2154C>G p.A718= | Silent (SNP) | VAF 45/759 reads (6%) | catalogued as COSV100542942; called by muse, mutect2
- DYSF | c.1569C>A p.I523= | Silent (SNP) | VAF 81/565 reads (14%) | called by muse, mutect2, varscan2
- FAM171A1 | c.1953G>C p.A651= | Silent (SNP) | VAF 14/300 reads (5%) | catalogued as COSV65315990; called by muse, mutect2
- NKAIN1 | c.18G>T p.G6= | Silent (SNP) | VAF 24/215 reads (11%) | called by muse, mutect2
- POU4F3 | c.186G>A p.A62= | Silent (SNP) | VAF 57/844 reads (7%) | catalogued as COSV57944103; called by muse, mutect2
- PRMT3 | c.1131T>A p.A377= | Silent (SNP) | VAF 52/724 reads (7%) | called by muse, mutect2
- RBMXL3 | c.1596G>A p.G532= | Silent (SNP) | VAF 183/425 reads (43%) | called by muse, mutect2, varscan2
- SBK1 | c.867G>A p.L289= | Silent (SNP) | VAF 43/508 reads (8%) | called by muse, mutect2
- SCGB1C2 | c.24G>T p.L8= | Silent (SNP) | VAF 60/626 reads (10%) | called by mutect2, varscan2
- TNR | c.51C>A p.I17= | Silent (SNP) | VAF 60/1086 reads (6%) | called by muse, mutect2
- TRPM8 | c.1680C>G p.P560= | Silent (SNP) | VAF 59/804 reads (7%) | catalogued as rs200545629, COSV100224595, COSV61223394; called by muse, mutect2
- VAV1 | c.2178G>C p.L726= | Silent (SNP) | VAF 56/908 reads (6%) | catalogued as COSV58392247; called by muse, mutect2
- ZFYVE16 | c.4438A>C p.R1480= | Silent (SNP) | VAF 50/830 reads (6%) | called by muse, mutect2
- ZNF367 | c.87G>C p.R29= | Silent (SNP) | VAF 20/236 reads (8%) | catalogued as rs747663934; called by muse, mutect2
- CACNA1A | c.3835-16C>A | Intron (SNP) | VAF 50/746 reads (7%) | called by muse, mutect2
- CGN | c.3197+55C>T | Intron (SNP) | VAF 11/161 reads (7%) | called by muse, mutect2
- EFR3A | c.-4C>A | 5'UTR (SNP) | VAF 42/648 reads (6%) | called by muse, mutect2
- HELZ2 | c.278+13G>A | Intron (SNP) | VAF 52/592 reads (9%) | catalogued as rs1176726225; called by muse, mutect2
- MCM4 | c.-87G>C | 5'UTR (SNP) | VAF 6/34 reads (18%) | called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 20/145 reads (14%) | called by muse, varscan2
- SAP25 | c.-128+73A>G | Intron (SNP) | VAF 20/101 reads (20%) | called by muse, mutect2
- WDR33 | c.*40_*43del | 3'UTR (DEL) | VAF 26/238 reads (11%) | called by mutect2, varscan2
